Surgical pathology report (de-identified scan), TCGA case TCGA-78-7540, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7540-01A (Primary Tumor).

[page 1 of 2]
LEFT LOWER LOBE

Clinical Notes:

LL lobectomy.

Bronchoalveolar carcinoma on FNA.

Two specimens received:

1: LEFT LOWER LOBE

Macroscopy:

Specimen consists of a left lower lobectomy which measures 130 x 65 x 90 mm. The pleura overlying the anterior basal segment is puckered and shows a small amount of adherent pale tissue. On sectioning the lung in this area, there is diffuse infiltration by pale and tan tumour which has a rubbery cut surface. The tumour appears to abut the lateral and diaphragmatic pleural surfaces. The lesion measures approximately 50 x 60 x 45 mm. The tumour also involves the posterior lateral basal and anterior basal segments. Tumour appears to surround a major segmental bronchus and extends close to the bronchial resection margin. The tumour does not appear to involve the medial margin.

[Tumour and diaphragmatic pleura, A; tumour and medial pleural surface, B; tumour and lateral pleural surface, C-D; bronchial resection margin, E; tumour and bronchus immediately adjacent to bronchial resection margin, F; hilar nodes, G; non-neoplastic lung, H.]

Microscopy:

Sections show a well-differentiated adenocarcinoma with a prominent mucinous bronchiolo-alveolar carcinoma component. Focally the tumour appears to be invasive. It closely abuts the pleural surface. Overlying this there is a thick organising fibrinous pleurisy. Although definite invasion of the pleura is not seen, there are suspicious features and special stains will be performed. No vascular or perineural invasion is seen. Small satellite deposits of tumour are scattered throughout the adjacent parenchyma. These are also identified in the parenchyma of the section taken of the bronchus immediately adjacent to the bronchial resection margin (Block F). Both the bronchial resection margin and the bronchus within the immediately adjacent section show no evidence of malignancy. No metastases to hilar lymph nodes are seen. The lung tissue away from the mass in block H shows no specific abnormality.

2: HILAR LYMPH NODE

Macroscopy:

Specimen consists of a single piece of grey firm tissue which measures 12 x 5 x 5 mm.

Microscopy:

Sections of the lymph node show carbon deposition and sinus histiocytosis but no evidence of metastatic malignancy.

Summary:

Left lower lobe and hilar lymph node:

- 1. Invasive well-differentiated adenocarcinoma with a predominant bronchiolo-alveolar carcinoma (mucinous type) pattern.*
- 2. Pleura probably not involved by carcinoma but confirmatory stains are being performed.*
- 3. No vascular or perineural invasion or lymph node metastases are seen.*
- 4. Bronchial resection margin free of tumour.*
- 5. T2N0Mx.*

3: BACK LIPOMA

Macroscopy:

Specimen consists of an irregularly shaped lobulated and slightly fragmented piece of fatty tissue measuring 95 x 70 x 25 mm. The external surface is smooth and yellow. The cut surface has a

[page 2 of 2]
[REDACTED]

homogeneous yellow appearance. No areas of haemorrhage or necrosis are identified. [REDACTED]

Microscopy:

Sections show lobulated mature adipose tissue. There is no evidence of malignancy.

Summary:

Back: The features are consistent with a lipoma.

P-01100 T-28000 M-81403 M-82503

P-01140 T-08000 M-09450

P-01100 T-IX000 M-88500

[REDACTED]

[REDACTED]

ADDENDUM REPORT

No pleural invasion is seen with special stains.

[REDACTED]

Source: NCI Genomic Data Commons file d036c957-c978-4153-9838-0b1b1a1dbe4b (TCGA-78-7540.95CAD21D-0A35-4AC7-9163-F5B7BB21E18D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).